Gene-level copy-number profile of tumor specimen C3L-02646-01 (profiled together with C3L-02646-05) from CPTAC case C3L-02646, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 74.8 years (27,321 days).
Specimen C3L-02646-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fadf1983-7f39-4ec2-8ef7-cdc671eab45e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02646-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/8382b53d-7f00-4f62-a984-c9968d92069f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 630; copy number 1: 1,689; copy number 2: 21,163; copy number 3: 11,470; copy number 4: 17,246; copy number 5: 2,768; copy number 6: 2,115; copy number 7: 1,042; copy number 8: 203; copy number 9: 149; copy number 10: 120; copy number 11: 135; copy number 12: 8; copy number 13: 55; copy number 14: 30; copy number 16: 2; copy number 17: 23; copy number 18: 4; copy number 26: 47; copy number 29: 9; copy number 50: 3.

Homozygous deletions (total copy number 0; autosomes only): 118 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:31,350,284–31,351,725, 1 gene: AC104071.1.
- chr9:20,658,309–23,956,444, 72 genes (broad region; genes not listed).
- chr10:61,406,642–65,880,289, 44 genes: TMEM26, TMEM26-AS1, CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1, RPL7AP50, AC012558.1, DBF4P1, RPL17P35, CYP2C61P, ANXA2P3, LINC02671, NEK4P3, MYL6P3, AL513321.1, AL592466.1, LINC01515.
- chr10:66,079,243–66,118,326, 1 gene (within-gene range 0–2): AC022017.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,712 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–184,629,019, 1,272 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:184,607,599–184,672,166, 1 gene, copy number 5: AL713852.1.
- chr3:93,843,764–198,123,232, 1,753 genes, copy number 6–14 (broad region; genes not listed).
- chr4:51,843,000–57,724,655, 122 genes, copy number 5–11 (broad region; genes not listed).
- chr5:80,487,969–81,892,721, 24 genes, copy number 13–29: FAM151B, RPS27AP9, RPL7P24, ANKRD34B, DBIP2, LINC01337, DHFR, AC008434.1, MTRNR2L2, MSH3, AC022493.2, AC022493.1, RASGRF2-AS1, RASGRF2, AC026427.2, AC026427.1, CKMT2-AS1, CKMT2, AC026436.1, ZCCHC9, ACOT12, SSBP2, AC026726.1, SEM1P1.
- chr6:69,672,757–83,065,841, 176 genes, copy number 5 (broad region; genes not listed).
- chr7:37,032–33,109,404, 572 genes, copy number 5 (broad region; genes not listed).
- chr7:33,128,988–33,129,143, 1 gene, copy number 5: AC074338.1.
- chr7:47,740,202–47,948,466, 1 gene, copy number 6 (within-gene range 2–6): PKD1L1.
- chr7:47,795,291–62,275,678, 204 genes, copy number 6–50 (broad region; genes not listed).
- chr7:64,207,090–74,122,525, 208 genes, copy number 6–16 (broad region; genes not listed).
- chr7:74,289,407–106,770,207, 617 genes, copy number 7–8 (within-gene range 4–13) (broad region; genes not listed).
- chr8:70,109,782–71,228,629, 16 genes, copy number 5 (within-gene range 4–5): NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1.
- chr8:76,162,119–83,408,900, 104 genes, copy number 6–8 (broad region; genes not listed).
- chr8:97,241,742–104,589,024, 169 genes, copy number 5–9 (broad region; genes not listed).
- chr8:113,600,310–114,295,839, 3 genes, copy number 8: AC103993.1, Y_RNA, AC064802.1.
- chr8:117,265,272–119,862,956, 30 genes, copy number 5–9: AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P.
- chr10:42,782,795–57,513,425, 248 genes, copy number 5–18 (within-gene range 5–19) (broad region; genes not listed).
- chr11:54,591,480–54,725,816, 11 genes, copy number 6: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr11:68,754,620–73,970,366, 174 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr12:67,265,842–77,317,234, 173 genes, copy number 5–6 (broad region; genes not listed).
- chr12:77,379,770–77,390,869, 1 gene, copy number 5: AC073591.1.
- chr13:96,883,842–98,024,296, 18 genes, copy number 5: HSP90AB6P, TULP3P1, AL353581.1, RN7SKP7, OXGR1, LINC00456, MBNL2, AL161430.1, RNA5SP37, RAP2A, AL442067.1, AL442067.2, PSMA6P4, AL359502.1, RPL7AP61, AL356580.1, IPO5, FTLP8.
- chr13:98,577,244–99,583,180, 29 genes, copy number 5 (within-gene range 2–5): STK24-AS1, NUS1P4, CYCSP35, CALM2P4, RN7SL60P, SLC15A1, DOCK9, DOCK9-AS1, AL161420.1, RPL7L1P12, RNU6-83P, DOCK9-DT, RPS6P23, UBAC2-AS1, GAPDHP22, UBAC2, RN7SKP9, H2AZP3, GPR18, GPR183, MIR623, HMGB3P4, CCR12P, TM9SF2, LINC01232, AL139035.1, LINC00449, LINC01039, CFL1P8.
- chr14:18,333,726–19,883,932, 78 genes, copy number 5 (broad region; genes not listed).
- chr17:142,789–1,400,222, 39 genes, copy number 5: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2, VPS53, AC015853.3, AC015853.1, AC027455.1, RPS4XP17, TLCD3A, GEMIN4, DBIL5P, GLOD4, AC087392.3, MRM3, AC087392.4, AC087392.5, NXN, AC087392.2, AC087392.1, AC036164.1, TIMM22, ABR, MIR3183, Metazoa_SRP, AC016292.2, AC016292.1, AC144836.1, BHLHA9, TRARG1, YWHAE, AC032044.2.
- chr17:2,557,753–5,619,424, 147 genes, copy number 5 (broad region; genes not listed).
- chr17:9,576,627–14,421,472, 86 genes, copy number 5–8 (broad region; genes not listed).
- chr17:20,008,865–20,319,026, 1 gene, copy number 6 (within-gene range 1–6): SPECC1.
- chr17:20,126,388–22,706,703, 111 genes, copy number 6–13 (broad region; genes not listed).
- chr18:45,034–2,049,510, 47 genes, copy number 6–8 (within-gene range 4–8): AP001005.1, TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1.
- chr18:14,053,951–14,157,342, 8 genes, copy number 12: AC006557.5, ZNF519, AC006557.4, AC006557.1, AC006557.3, FRG2LP, AC006557.2, NF1P5.
- chr20:87,250–3,239,559, 105 genes, copy number 6 (broad region; genes not listed).
- chr20:8,998,849–12,381,255, 46 genes, copy number 6: Metazoa_SRP, PLCB4, LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2.
- chr21:13,038,160–13,067,033, 2 genes, copy number 6: ANKRD30BP2, RNU6-614P.
- chr22:46,053,869–46,113,928, 1 gene, copy number 5 (within-gene range 3–5): MIRLET7BHG.
- chr22:46,091,044–50,801,309, 114 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,400. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
